CCG case CUPP-B5XK — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/487029b5-88e4-4c7f-881e-74728bfab65c

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Japan; Year of birth: 1944; Vital status: Dead; Days to death: 563 days (1.5 years); Year of death: 2013; Cause of death: Cancer Related.

Diagnoses (3)
1. Squamous cell carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8070/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 67.3 years (24,569 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 8th; AJCC clinical T: T0; AJCC clinical N: N2c; AJCC clinical M: M0; AJCC clinical stage: Stage IVB; AJCC pathologic T: T0; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVB; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 29; Lymph nodes tested: 36; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R1; Timepoint category: First Treatment.
2. Progression of the bone (histology not recorded by GDC). Age at diagnosis: 68.4 years (24,968 days); Year of diagnosis: 2012; Days to diagnosis: 399 days (1.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.
3. Progression of the lymph node (histology not recorded by GDC). Age at diagnosis: 68.4 years (24,968 days); Year of diagnosis: 2012; Days to diagnosis: 399 days (1.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80; ECOG performance status: 1.
- Day 399 (progression): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 399 days (1.1 years).
- Day 399 (progression): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 399 days (1.1 years).
- Follow-up contact recording only the day: day 563.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 161 cm; BMI: 22.4.
- Timepoint category: Prior to Diagnosis; Comorbidities: Arrhythmia / Diabetes, NOS.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1976; Tobacco smoking quit year: 1996.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B5XK-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B5XK-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 21; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
